CCDI case PBCPGG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/4c6316ce-aaca-40b0-bf4b-97909ecaf912

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.4 years (155 days).

Biospecimens (2 samples)
- Sample 0DWNR5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWNTO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
